Somatic mutation profile of tumor specimen ALCH-B2VN-TTP1-A (aliquot ALCH-B2VN-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2VN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.1 years (28,909 days).
Specimen ALCH-B2VN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8559a10-80e5-4e90-8512-84f80115ad69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2VN-NB1-A (Blood Derived Normal), aliquot ALCH-B2VN-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2441808-8507-4672-b41b-f059753c38c3

The open-access MAF lists 63 somatic variants for this specimen: 45 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 13, Nonsense Mutation 3, Intron 2, 3'Flank 1, 5'UTR 1, Translation Start Site 1, RNA 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPNT2 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1429774253; called by muse, mutect2
- CHAF1B | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.151); catalogued as rs745523995, COSV58439944; called by muse, mutect2
- GLTPD2 | c.251G>C p.R84P | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as COSV58702360; called by muse, mutect2, varscan2
- INTS5 | c.1253C>A p.S418* | Nonsense Mutation (SNP) | VAF 14/242 reads (6%) | catalogued as COSV57953964; called by muse, mutect2
- KLHL14 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as rs750871626, COSV63832002; called by muse, mutect2
- MARK4 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as rs1277909022; called by muse, varscan2
- NPC1L1 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 62/501 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56927323; called by muse, mutect2, varscan2
- OR8H2 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772150732, COSV57947484; called by muse, mutect2
- RFX6 | c.10G>T p.V4F | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); catalogued as rs1291016036; called by muse, mutect2
- RPS19 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 31/632 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as CM167143; called by muse, mutect2
- SEMA5A | c.2813G>A p.R938Q | Missense Mutation (SNP) | VAF 40/454 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.661); catalogued as rs371373696; called by muse, mutect2
- SULT4A1 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs11542811, COSV50780467, COSV99970522; called by muse, mutect2, varscan2
- XKR7 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248696179, COSV73813132; called by muse, mutect2, varscan2
- ACACB | c.1235C>A p.T412K | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRG2 | c.598T>C p.C200R (on ENST00000379869 / NM_001079858.3; = p.C197R on NM_005756.4) | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CACNA1A | c.6946G>T p.G2316W | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- COL4A5 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FGF13 | c.79T>A p.C27S | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- GHR | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 77/875 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- GNPDA1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- HBP1 | c.110G>T p.C37F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- HTT | c.4376G>A p.R1459Q | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIF6 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MROH2B | c.2936G>C p.S979T | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- NOMO1 | c.2330del p.P777Lfs*16 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, varscan2
- OGDH | c.1306G>C p.G436R | Missense Mutation (SNP) | VAF 15/398 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- OR4M1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PAK3 | c.942G>A p.M314I (on ENST00000262836 / NM_001324328.2; = p.M299I on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.354); called by muse, mutect2
- PCMTD1 | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.652); called by muse, mutect2
- PELP1 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2
- PELP1 | c.1458G>T p.L486F | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.712); called by muse, mutect2
- QSER1 | c.403C>G p.R135G (on ENST00000399302; = p.R264G on NM_001076786.3) | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBMXL2 | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- RIMS1 | c.2477G>T p.R826L | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RTL10 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2
- SPIB | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYTL4 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.894); called by muse, mutect2
- TPD52 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 101/529 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRIM51 | c.1237C>A p.L413M | Missense Mutation (SNP) | VAF 10/334 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRMT13 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2
- TSC2 | c.5068+6_5068+11del | Splice Region (DEL) | VAF 46/284 reads (16%) | called by mutect2, pindel, varscan2
- USH2A | c.13712A>T p.E4571V | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.398); called by muse, mutect2
- ZC3H3 | c.320A>G p.Q107R | Missense Mutation (SNP) | VAF 13/323 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- ZNF7 | c.1123T>G p.S375A | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2
- ZNF791 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 8/169 reads (5%) | called by muse, mutect2
- CNTNAP4 | c.3507T>A p.S1169= | Silent (SNP) | VAF 9/276 reads (3%) | called by muse, mutect2
- DSP | c.3321C>A p.L1107= | Silent (SNP) | VAF 48/378 reads (13%) | called by muse, mutect2, varscan2
- IFT140 | c.1146G>T p.T382= | Silent (SNP) | VAF 26/650 reads (4%) | catalogued as COSV101276308; called by muse, mutect2
- INCENP | c.678G>A p.R226= | Silent (SNP) | VAF 18/213 reads (8%) | called by muse, mutect2
- OVOL2 | c.414C>T p.L138= | Silent (SNP) | VAF 45/271 reads (17%) | catalogued as COSV53860230; called by muse, mutect2, varscan2
- PPM1H | c.822G>A p.V274= | Silent (SNP) | VAF 33/233 reads (14%) | called by muse, mutect2, varscan2
- PRICKLE4 | c.975C>T p.T325= (on ENST00000359201; = p.T365= on NM_013397.6) | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs761493165; called by muse, mutect2
- RECQL5 | c.828C>G p.A276= | Silent (SNP) | VAF 65/341 reads (19%) | called by muse, mutect2, varscan2
- SETD2 | c.7449C>G p.V2483= | Silent (SNP) | VAF 44/268 reads (16%) | called by muse, mutect2, varscan2
- SLC8A2 | c.582C>T p.H194= | Silent (SNP) | VAF 28/258 reads (11%) | called by muse, mutect2, varscan2
- SUPT16H | c.702A>T p.A234= | Silent (SNP) | VAF 35/258 reads (14%) | called by muse, mutect2, varscan2
- TMEM82 | c.684G>A p.L228= | Silent (SNP) | VAF 78/240 reads (33%) | called by muse, mutect2, varscan2
- TNC | c.627C>T p.D209= | Silent (SNP) | VAF 77/374 reads (21%) | catalogued as rs138151398; called by muse, mutect2, varscan2
- AC005041.1 | chr2:74391808 G>T | 3'Flank (SNP) | VAF 61/259 reads (24%) | catalogued as rs890686653; called by muse, mutect2, varscan2
- CACNA1C | c.1217+315G>A | Intron (SNP) | VAF 28/636 reads (4%) | catalogued as rs1131653, COSV59696899; ClinVar: uncertain significance; called by muse, mutect2
- MIR300 | n.26C>G | RNA (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2
- NDUFA10 | c.460+31C>G | Intron (SNP) | VAF 78/380 reads (21%) | called by muse, mutect2, varscan2
- ZNF391 | c.-302C>G | 5'UTR (SNP) | VAF 31/172 reads (18%) | called by muse, mutect2, varscan2
